Somatic mutation profile of tumor specimen TCGA-BR-8687-01A (aliquot TCGA-BR-8687-01A-11D-2394-08) from TCGA case TCGA-BR-8687, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.0 years (24,472 days).
Specimen TCGA-BR-8687-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db850535-1b80-47cc-aafd-35659a5ff947.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8687-10A (Blood Derived Normal), aliquot TCGA-BR-8687-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d1dea41-91e5-45b4-b3b1-8eeb750159dd

The open-access MAF lists 196 somatic variants for this specimen: 148 protein-altering or splice-affecting, 45 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 45, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 3, 3'UTR 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV55951778; called by muse, mutect2, varscan2
- ACSL4 | c.2020A>G p.S674G (on ENST00000340800 / NM_022977.2; = p.S633G on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV61614374; called by muse, mutect2, varscan2
- ACSM1 | c.102A>C p.E34D | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54635957; called by muse, mutect2, varscan2
- ADAMTS15 | c.2045G>T p.C682F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54505613; called by muse, mutect2, varscan2
- ANGPT4 | c.1443G>A p.W481* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as COSV67921589; called by muse, mutect2, varscan2
- ANKRD6 | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60231553; called by muse, mutect2, varscan2
- ARHGAP19 | c.1028A>C p.K343T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV57393002; called by muse, mutect2, varscan2
- BSN | c.982A>C p.S328R | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV56518049; called by muse, mutect2, varscan2
- BTBD9 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV58426178; called by muse, mutect2, varscan2
- BTNL8 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 46/499 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV51458777; called by muse, mutect2
- CCDC191 | c.696A>C p.Q232H | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55672276; called by muse, mutect2, varscan2
- CDC25C | c.950A>C p.K317T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV60399483; called by muse, mutect2, varscan2
- CDK2 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 50/716 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs997202140, COSV57186609; called by muse, mutect2
- CELSR1 | c.5191G>A p.A1731T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV53090344; called by muse, mutect2, varscan2
- CHD5 | c.5473C>T p.L1825F | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1392018286, COSV52414806; called by muse, mutect2
- CNTN5 | c.1494A>C p.E498D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54311548; called by muse, mutect2, varscan2
- CSH1 | c.599A>G p.E200G | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60242200; called by muse, mutect2, varscan2
- CTR9 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV63728605; called by muse, mutect2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- DMXL1 | c.2959T>G p.L987V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV60711755; called by muse, mutect2, varscan2
- DNAH7 | c.2112A>C p.E704D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV56765417; called by muse, mutect2, varscan2
- DNAJC17 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55025012; called by muse, mutect2, varscan2
- DOCK11 | c.4781A>T p.E1594V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52239181; called by muse, mutect2, varscan2
- DOP1B | c.5930T>C p.L1977P | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV67693432; called by muse, mutect2, varscan2
- DYNC2H1 | c.342A>C p.Q114H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV62094424, COSV62097090; called by muse, mutect2, varscan2
- EOLA1 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63734119; called by muse, mutect2, varscan2
- ERICH3 | c.4424G>T p.R1475L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV58606884, COSV58611028; called by muse, mutect2
- EVC2 | c.3020A>G p.K1007R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as COSV60394241; called by mutect2, varscan2
- FAM135B | c.4078A>G p.T1360A | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV52725651; called by muse, mutect2
- FKTN | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV56309841; called by muse, mutect2, varscan2
- GABBR2 | c.1880A>C p.K627T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV52304088; called by muse, mutect2, varscan2
- GAS7 | c.872A>C p.K291T (on ENST00000432992 / NM_201433.2; = p.K151T on NM_003644.3) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV60436663; called by muse, mutect2
- GATA3 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs374919553; called by muse, mutect2, varscan2
- GNAZ | c.762C>G p.I254M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV50738127; called by muse, mutect2, varscan2
- GNAZ | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV50738143; called by muse, mutect2
- GPR143 | c.1172A>C p.K391T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.025); catalogued as COSV66632480; called by muse, mutect2, varscan2
- GSDMC | c.1312T>G p.F438V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52695485; called by muse, mutect2, varscan2
- HECTD1 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.19); catalogued as COSV67946300; called by muse, mutect2, varscan2
- HELZ | c.1970T>C p.L657P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV62378542; called by muse, mutect2, varscan2
- HSP90AB1 | c.490T>G p.S164A | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV62334568; called by muse, mutect2, varscan2
- IFI16 | c.2089A>C p.N697H (on ENST00000295809 / NM_001364867.2; = p.N641H on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.737); catalogued as rs969556751, COSV55534172; called by muse, mutect2, varscan2
- IMMT | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs969250947, COSV54487031; called by muse, mutect2, varscan2
- IRX4 | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51472710; called by muse, mutect2, varscan2
- ITSN1 | c.2924A>G p.K975R | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as COSV66083087; called by muse, mutect2
- JMJD1C | c.5435A>C p.K1812T | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59514612; called by muse, mutect2, varscan2
- KANK4 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV62986812; called by muse, mutect2, varscan2
- KAT14 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as rs150894437; called by muse, mutect2, varscan2
- KIAA1217 | c.1811A>G p.N604S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56816850; called by muse, mutect2, varscan2
- KIAA1586 | c.1636A>G p.R546G | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1429007958, COSV66056668; called by muse, mutect2, varscan2
- KIF15 | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV100392945; called by muse, mutect2, varscan2
- KIF17 | c.2752G>T p.A918S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV56123887; called by muse, mutect2
- KIF5C | c.613A>C p.S205R | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68481291; called by muse, mutect2, varscan2
- KIT | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.159); catalogued as COSV55400864; called by muse, mutect2, varscan2
- LRIF1 | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63897378; called by muse, mutect2
- LRP2 | c.1412A>C p.N471T | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV55553650; called by muse, mutect2, varscan2
- LRP6 | c.1284A>C p.E428D | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV53787576; called by muse, mutect2, varscan2
- LVRN | c.1492T>G p.F498V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63497218; called by muse, mutect2
- MAP3K9 | c.1376A>C p.K459T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV67121367; called by muse, mutect2
- MED17 | c.1638G>T p.W546C | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52601017; called by muse, mutect2, varscan2
- MOB3C | c.-49G>T | Splice Region (SNP) | VAF 23/61 reads (38%) | catalogued as COSV99596351; called by muse, mutect2, varscan2
- MPPED2 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.179); catalogued as COSV100813491, COSV63898371; called by muse, mutect2, varscan2
- MRPS36 | c.16A>G p.M6V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as COSV56507939; called by muse, mutect2, varscan2
- MSGN1 | c.401A>T p.K134M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55262909; called by muse, mutect2, varscan2
- MYEF2 | c.1706T>G p.F569C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51047747; called by muse, mutect2, varscan2
- MYO3A | c.4455G>T p.E1485D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.046); catalogued as rs1294039852, COSV56329576; called by muse, mutect2, varscan2
- MYO9A | c.2218A>C p.S740R | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as rs959344025, COSV61851166; called by muse, mutect2, varscan2
- MYOM3 | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58393897; called by muse, mutect2, varscan2
- MYT1 | c.1220A>G p.Q407R | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV60505887; called by muse, mutect2
- NBEA | c.6766C>T p.R2256W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV59785203; called by muse, mutect2, varscan2
- NEXMIF | c.3338A>G p.K1113R | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1569335122; called by muse, mutect2
- NF2 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1395872275, COSV58523988; called by muse, mutect2, varscan2
- NLRP4 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs140761924; called by muse, mutect2, varscan2
- NLRP8 | c.1760T>C p.L587P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52587329; called by muse, varscan2
- NLRP8 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs759131290, COSV52587344; called by muse, varscan2
- NOC3L | c.1571A>C p.K524T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV64929905; called by muse, mutect2, varscan2
- NOX1 | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54194594, COSV99471791; called by muse, mutect2, varscan2
- NUP107 | c.2130A>C p.E710D | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV57494849; called by muse, mutect2
- NUP35 | c.940A>C p.S314R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV54557927; called by muse, mutect2
- NWD1 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs376481084; called by muse, mutect2, varscan2
- NXF3 | c.847A>C p.S283R | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV67703566; called by muse, mutect2, varscan2
- OR10S1 | c.181A>C p.T61P | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV73342798; called by muse, mutect2
- OR14J1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65845682; called by muse, mutect2
- OR2D2 | c.812C>G p.S271W | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV55056460, COSV55057158; called by muse, mutect2, varscan2
- OR2M5 | c.926A>T p.K309M | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV63546005, COSV63546296, COSV63546664; called by muse, mutect2, varscan2
- OR4A5 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV60521706, COSV60524684; called by muse, mutect2, varscan2
- OR4S2 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 43/106 reads (41%) | catalogued as COSV56746962; called by muse, mutect2, varscan2
- OR5B3 | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.182); catalogued as COSV58677350; called by muse, mutect2, varscan2
- OR5D16 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755221016, COSV65722006; called by muse, mutect2, varscan2
- OR8J3 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.41); catalogued as COSV56880878; called by muse, mutect2, varscan2
- OSBPL6 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV51918165; called by muse, mutect2, varscan2
- PACSIN2 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs775794255, COSV54316411, COSV99606358; called by mutect2, varscan2
- PCDH15 | c.1775C>A p.A592E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV57313353; called by muse, mutect2, varscan2
- PCDHA10 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.415); catalogued as rs1554149609, COSV56492711; called by muse, mutect2, varscan2
- PDILT | c.1462T>C p.F488L | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56701969; called by muse, mutect2, varscan2
- PER3 | c.2785T>G p.L929V | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62705931; called by muse, mutect2, varscan2
- PEX3 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV62568717; called by muse, mutect2, varscan2
- PIK3CG | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV63248660; called by muse, mutect2, varscan2
- PIK3R6 | c.1314G>A p.R438= | Splice Region (SNP) | VAF 36/52 reads (69%) | catalogued as COSV61003231; called by muse, mutect2, varscan2
- PKD1 | c.12292G>A p.A4098T (on ENST00000262304 / NM_001009944.3; = p.A4097T on NM_000296.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.84); catalogued as rs1346816281, COSV51916501; called by muse, mutect2
- PKHD1 | c.3799G>A p.A1267T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV61875919; called by muse, mutect2, varscan2
- PLXNB3 | c.4853T>G p.V1618G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV62797454; called by muse, mutect2, varscan2
- PPFIA3 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.018); catalogued as COSV53256227; called by muse, mutect2, varscan2
- PRKCH | c.1492T>G p.F498V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60648332; called by muse, mutect2, varscan2
- PRKD2 | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52186883; called by muse, mutect2, varscan2
- PRKD2 | c.632C>A p.T211N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52186892; called by muse, mutect2, varscan2
- PTCHD4 | c.1501A>G p.S501G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59784470; called by muse, mutect2, varscan2
- RBM47 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55935214; called by muse, mutect2, varscan2
- RHO | c.859T>G p.F287V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV56213545; called by muse, mutect2, varscan2
- RNF213 | c.14089C>T p.P4697S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.052); catalogued as COSV60397727; called by muse, mutect2, varscan2
- RPN2 | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs139589912; called by muse, mutect2
- RSPH4A | c.1073A>T p.K358M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57634717; called by muse, mutect2, varscan2
- RUNX1T1 | c.1117C>T p.R373* (on ENST00000265814 / NM_001198628.1; = p.R346* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | catalogued as COSV56143680, COSV56151272; called by muse, mutect2
- SALL2 | c.2096A>G p.K699R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373066758; called by muse, mutect2, varscan2
- SCG2 | c.1522T>G p.L508V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV59540094; called by muse, mutect2, varscan2
- SLAMF1 | c.891C>A p.F297L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99349385; called by muse, mutect2
- SLC24A5 | c.1296A>C p.E432D | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV51047722; called by muse, mutect2, varscan2
- SLC35D1 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52430023, COSV52431350; called by muse, mutect2
- SLIT2 | c.3172A>G p.K1058E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1272275751, COSV56572894; called by muse, mutect2, varscan2
- SPTBN4 | c.7375G>T p.D2459Y | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52539917; called by muse, mutect2, varscan2
- SSH2 | c.1973A>C p.K658T | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52172568; called by muse, mutect2, varscan2
- SUPT6H | c.1865A>G p.K622R | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs1267795508, COSV58927416; called by muse, mutect2
- SUPT6H | c.2822A>G p.K941R | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.048); catalogued as COSV58927425; called by muse, mutect2, varscan2
- SYT10 | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1565495250, COSV57340683, COSV99950875; called by muse, mutect2, varscan2
- TASOR2 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV60167525; called by muse, mutect2
- TBC1D1 | c.1471T>G p.F491V | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV54719184; called by muse, mutect2, varscan2
- TENM1 | c.2891T>G p.V964G | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64432222; called by muse, mutect2, varscan2
- TFIP11 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1416883701, COSV53226230; called by muse, mutect2, varscan2
- THAP9 | c.929T>G p.L310R | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV56356477; called by muse, mutect2
- TMCC3 | c.1131G>A p.Q377= | Splice Region (SNP) | VAF 5/72 reads (7%) | catalogued as rs920563768, COSV54154546; called by muse, mutect2
- TNFSF8 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV56342541; called by muse, mutect2, varscan2
- TNR | c.1669A>G p.S557G | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54886056; called by muse, mutect2, varscan2
- TRIML2 | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.281); catalogued as COSV58716205; called by muse, mutect2
- TRPV3 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV56791541; called by muse, mutect2, varscan2
- TTN | c.48189A>C p.K16063N (on ENST00000591111; = p.K8639N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/279 reads (5%) | PolyPhen benign (0.075); catalogued as COSV60068944; called by muse, mutect2
- UBR1 | c.3095A>C p.K1032T | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51929860; called by muse, mutect2
- XPOT | c.652T>G p.L218V | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV60345456; called by muse, mutect2, varscan2
- ZNF135 | c.508A>C p.S170R (on ENST00000313434 / NM_001289401.2; = p.S182R on NM_003436.4) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV57882217; called by muse, mutect2
- ZNF274 | c.1663A>G p.R555G (on ENST00000610905; = p.R450G on NM_016324.3) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58764486; called by muse, mutect2, varscan2
- ZNF425 | c.1936A>C p.S646R | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV65201326; called by muse, mutect2, varscan2
- ZNF674 | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV101345044; called by muse, mutect2, varscan2
- ARID1A | c.5735A>C p.D1912A | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, varscan2
- ARID1A | c.5742_5746del p.M1914Ifs*5 | Frame Shift Del (DEL) | VAF 36/93 reads (39%) | called by pindel, varscan2
- BTNL8 | c.1404del p.E469Rfs*101 | Frame Shift Del (DEL) | VAF 8/97 reads (8%) | called by pindel, varscan2*
- NEDD9 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- SPANXN5 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.069); called by muse, mutect2
- TRAV13-1 | c.176T>G p.L59R | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ZNF518A | c.1988del p.P663Lfs*23 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- ACSM2B | c.498A>G p.E166= | Silent (SNP) | VAF 53/238 reads (22%) | catalogued as rs1195056307, COSV61657911; called by muse, mutect2, varscan2
- ACSM3 | c.1713G>A p.G571= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV55501489; called by muse, mutect2, varscan2
- ADGRB3 | c.96T>G p.T32= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV65395994; called by muse, mutect2
- ANKH | c.1245C>T p.L415= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs879754746, COSV52480989; called by muse, mutect2
- ARMCX5 | c.162T>C p.A54= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV55766633; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.624A>G p.K208= | Silent (SNP) | VAF 48/247 reads (19%) | catalogued as COSV63437972; called by muse, mutect2, varscan2
- ATP10D | c.3574T>C p.L1192= | Silent (SNP) | VAF 11/207 reads (5%) | catalogued as COSV56707505; called by muse, mutect2
- CACNA1F | c.5751C>T p.F1917= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1352913123, COSV59903205; called by muse, mutect2
- CCDC88B | c.2226G>A p.E742= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV57266218; called by muse, mutect2, varscan2
- CHD9 | c.1491T>C p.Y497= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1486977777, COSV68298228; called by muse, mutect2, varscan2
- CNBD1 | c.1266A>G p.E422= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV73072749, COSV73073471; called by muse, mutect2, varscan2
- COL12A1 | c.3681A>G p.E1227= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV59396270; called by muse, mutect2, varscan2
- COL25A1 | c.135C>T p.A45= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV67650403; called by muse, mutect2, varscan2
- DNMT3A | c.615G>A p.E205= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV53052905; called by muse, mutect2, varscan2
- FAT1 | c.4203C>T p.H1401= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV71674001; called by muse, mutect2
- GABRQ | c.534C>T p.T178= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV64782099; called by muse, mutect2
- GTF2IRD2 | c.1992G>A p.K664= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs1349102334, COSV100736443; called by muse, mutect2, varscan2
- HEATR3 | c.618A>G p.S206= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs781088526, COSV53529292; called by muse, mutect2, varscan2
- HSPB1 | c.93G>A p.Q31= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs761051758, COSV50349187; called by muse, mutect2
- HYDIN | c.9831C>T p.S3277= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs373475787; called by muse, mutect2, varscan2
- IRGC | c.1008C>T p.N336= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs553364902, COSV54984169; called by muse, mutect2, varscan2
- LAMA3 | c.5271C>T p.C1757= (on ENST00000313654 / NM_198129.4; = p.C148= on NM_000227.6) | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs774968902, COSV52534857; called by muse, mutect2, varscan2
- LCOR | c.3813A>G p.E1271= | Silent (SNP) | VAF 73/142 reads (51%) | catalogued as COSV53715956; called by muse, mutect2, varscan2
- LDLRAD3 | c.861A>G p.Q287= | Silent (SNP) | VAF 23/240 reads (10%) | catalogued as COSV59682693; called by muse, mutect2
- LTN1 | c.4074A>C p.L1358= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV63733834; called by muse, mutect2, varscan2
- MAGEB18 | c.154T>C p.L52= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV57464058; called by muse, mutect2
- NAV1 | c.987C>T p.D329= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1415034521, COSV55217652; called by muse, mutect2, varscan2
- NDUFA9 | c.1071C>T p.R357= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV56929289; called by muse, mutect2, varscan2
- NTSR1 | c.1242C>A p.R414= | Silent (SNP) | VAF 322/380 reads (85%) | catalogued as rs73918683, COSV65138658; called by muse, mutect2, varscan2
- NUTM1 | c.2061C>T p.A687= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV59216855; called by muse, mutect2, varscan2
- PCDHB5 | c.1344C>T p.P448= | Silent (SNP) | VAF 48/214 reads (22%) | catalogued as COSV50651903; called by muse, mutect2, varscan2
- PHF12 | c.1578G>A p.A526= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as rs147697011; called by muse, mutect2, varscan2
- PIGT | c.225G>A p.Q75= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV54126322; called by muse, mutect2, varscan2
- PLA2G15 | c.723T>G p.A241= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV54723224; called by muse, mutect2, varscan2
- PPP1R26 | c.822G>A p.V274= | Silent (SNP) | VAF 94/197 reads (48%) | catalogued as rs750583506, COSV63355610; called by muse, mutect2, varscan2
- PSG4 | c.745T>C p.L249= | Silent (SNP) | VAF 55/228 reads (24%) | catalogued as COSV54935795, COSV54938698; called by muse, mutect2, varscan2
- RAG1 | c.447T>G p.T149= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV55025360; called by muse, mutect2, varscan2
- RPRD2 | c.1086G>A p.V362= | Silent (SNP) | VAF 12/210 reads (6%) | catalogued as rs781916290, COSV64820341; called by muse, mutect2
- SPART | c.1422C>A p.T474= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV62085377; called by muse, mutect2, varscan2
- STAP1 | c.471C>T p.S157= | Silent (SNP) | VAF 85/175 reads (49%) | catalogued as rs765642792, COSV55327747; called by muse, mutect2, varscan2
- TMC8 | c.1569G>T p.R523= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100573760; called by muse, mutect2, varscan2
- TNNI3 | c.498C>T p.S166= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV52571857; called by muse, mutect2, varscan2
- TOGARAM1 | c.411T>C p.Y137= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as COSV61888168; called by muse, mutect2, varscan2
- TUBGCP2 | c.1797G>A p.A599= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1021562112, COSV53305268; called by muse, mutect2, varscan2
- ZNF569 | c.421T>C p.L141= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV57595507; called by muse, mutect2, varscan2
- ATAD3B | c.*30C>T | 3'UTR (SNP) | VAF 14/104 reads (13%) | catalogued as rs759328778, COSV58020803; called by muse, varscan2
- CTBP2 | c.58+12534T>C | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100456586; called by mutect2, varscan2
- NXF5 | n.846G>A | RNA (SNP) | VAF 9/80 reads (11%) | catalogued as COSV53791064; called by muse, mutect2, varscan2
